Somatic mutation profile of tumor specimen TCGA-HN-A2OB-01A (aliquot TCGA-HN-A2OB-01A-21D-A27P-09) from TCGA case TCGA-HN-A2OB, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Lobular carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIB; Age at diagnosis: 45.6 years (16,672 days).
Specimen TCGA-HN-A2OB-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 72cb6882-7171-4472-a7d7-7977f31a6d40.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HN-A2OB-10B (Blood Derived Normal), aliquot TCGA-HN-A2OB-10B-01D-A27P-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/85ede25d-b960-4d88-980a-be9f90b79633

The open-access MAF lists 13 somatic variants for this specimen: 12 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 12, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1624G>A p.E542K | Missense Mutation (SNP) | VAF 16/61 reads (26%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.912); catalogued as rs121913273, CM153078, COSV55873227, COSV55894248; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- BAP1 | c.642C>G p.I214M | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as COSV99963793; called by muse, varscan2
- BCAS3 | c.1331G>C p.R444P | Missense Mutation (SNP) | VAF 7/96 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV101175682, COSV101175922; called by muse, mutect2
- C1GALT1C1 | c.652T>A p.S218T | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.39); catalogued as COSV100485608; called by muse, mutect2, varscan2
- CCDC80 | c.2617G>A p.G873R | Missense Mutation (SNP) | VAF 4/74 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1239346844, COSV52818060; called by muse, mutect2
- DSG4 | c.398G>A p.R133Q | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT tolerated (0.34); PolyPhen benign (0.121); catalogued as rs143110911, COSV57397813; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FASN | c.2058C>A p.F686L | Missense Mutation (SNP) | VAF 3/30 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.312); catalogued as COSV100147632, COSV100148339; called by muse, mutect2
- GRK7 | c.313G>A p.A105T | Missense Mutation (SNP) | VAF 8/122 reads (7%) | SIFT tolerated (0.2); PolyPhen benign (0.005); catalogued as COSV99379718; called by muse, mutect2
- HTT | c.7328A>C p.K2443T | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.994); catalogued as COSV100750652; called by muse, mutect2, varscan2
- OR52B2 | c.178C>T p.P60S | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV101603936; called by muse, mutect2, varscan2
- RNF170 | c.148C>G p.Q50E | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.15); catalogued as COSV99533709; called by muse, mutect2, varscan2
- SRM | c.422C>T p.A141V | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV65384448; called by muse, mutect2, varscan2
- MAN1C1 | c.471G>T p.L157= | Silent (SNP) | VAF 3/43 reads (7%) | catalogued as COSV99848132; called by muse, mutect2
